Somatic mutation profile of tumor specimen TCGA-HC-8261-01A (aliquot TCGA-HC-8261-01A-11D-2260-08) from TCGA case TCGA-HC-8261, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.9 years (17,874 days).
Specimen TCGA-HC-8261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 438839f4-6ef0-4733-9272-80fc1b1b4661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8261-10A (Blood Derived Normal), aliquot TCGA-HC-8261-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4db76be4-9e82-447c-9987-2daf51f12b83

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 10, Nonsense Mutation 3, Intron 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 64/169 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs193921065, COSV61652814, COSV61652918; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CDH3 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1239871777, COSV50558058; called by muse, mutect2, varscan2
- CFAP43 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780074336, COSV53375969; called by muse, mutect2, varscan2
- CHD9 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68298190; called by muse, mutect2
- CHGA | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV50895418, COSV99381017; called by muse, mutect2, varscan2
- DCHS1 | c.3691C>G p.P1231A | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55035644; called by muse, mutect2, varscan2
- ETNPPL | c.445A>T p.I149F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56595780; called by muse, mutect2, varscan2
- FAM53B | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55102354; called by muse, mutect2
- HLA-G | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.099); catalogued as COSV64405697; called by muse, mutect2
- HTR1D | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58448080; called by muse, mutect2, varscan2
- NCOR1 | c.5581A>G p.S1861G | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs543425229, COSV51974770; called by muse, mutect2, varscan2
- SHROOM3 | c.4978C>T p.Q1660* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV56029249; called by muse, mutect2
- SRP54 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV53739806; called by muse, mutect2, varscan2
- TDP1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.505); catalogued as rs766032249, COSV59643116; called by muse, mutect2, varscan2
- TTC6 | c.1127C>T p.T376I (on ENST00000267368; = p.T1742I on NM_001310135.3) | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1327166670, COSV57448916; called by muse, mutect2, varscan2
- ZNF142 | c.3946G>T p.E1316* (on ENST00000411696 / NM_001379660.1; = p.E1116* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV68743732; called by muse, mutect2
- ZNF468 | c.957G>C p.R319S | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs752092917, COSV54694697, COSV54697533; called by muse, mutect2, varscan2
- CHD8 | c.6732A>T p.R2244= (on ENST00000646647 / NM_001170629.2; = p.R1965= on NM_020920.4) | Silent (SNP) | VAF 15/255 reads (6%) | catalogued as COSV63036833; called by muse, mutect2
- CSMD1 | c.5361C>T p.N1787= (on ENST00000520002; = p.N1786= on NM_033225.6) | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs34443453; called by muse, mutect2, varscan2
- EEF2K | c.363C>T p.T121= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs199516774, COSV53781897; called by muse, mutect2, varscan2
- FAM120A | c.2757C>T p.C919= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs376063622; called by muse, mutect2, varscan2
- HNF1A | c.1014C>T p.G338= | Silent (SNP) | VAF 24/228 reads (11%) | catalogued as rs763412043, COSV57459631; called by muse, mutect2, varscan2
- JAG2 | c.1056C>T p.T352= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV59308961; called by muse, mutect2
- NCK2 | c.237G>A p.K79= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV51891386; called by muse, mutect2, varscan2
- RTL5 | c.300G>A p.S100= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101030159, COSV65453422; called by muse, mutect2, varscan2
- SLC39A5 | c.609T>A p.P203= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV57191729; called by muse, mutect2, varscan2
- USP8 | c.3153T>C p.Y1051= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs780599238, COSV56164292; called by muse, varscan2
- GBA3 | c.59-8302dup | Intron (INS) | VAF 52/172 reads (30%) | called by mutect2, pindel, varscan2
- Unknown | chr21:16071121 T>C | IGR (SNP) | VAF 50/200 reads (25%) | called by muse, mutect2, varscan2
